Gene-level copy-number profile of tumor specimen MP2PRT-PAVHTD-TBP1-A from MP2PRT case MP2PRT-PAVHTD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (729 days).
Specimen MP2PRT-PAVHTD-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 09b971ba-103a-4532-b96d-3e230e026fba.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVHTD-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/15cca80e-20d6-4be5-848e-65acf3dd39ee

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 168; copy number 1: 65; copy number 2: 58,170.

Homozygous deletions (total copy number 0; autosomes only): 168 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:21,397,987–21,417,492, 3 genes: PPP1R11P1, AL592309.1, AL592309.2.
- chr1:246,690,047–246,691,821, 1 gene: AL591848.1.
- chr2:87,439,523–87,459,044, 1 gene (within-gene range 0–2): LINC01943.
- chr4:39,287,456–39,366,375, 2 genes (within-gene range 0–2): RFC1, RNU6-32P.
- chr5:79,170,234–79,191,747, 2 genes (within-gene range 0–2): RNY3P1, AC016559.2.
- chr7:38,257,879–38,265,678, 1 gene (within-gene range 0–1): TRGC1.
- chr7:38,273,587–38,329,643, 9 genes (within-gene range 0–1): TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2.
- chr7:72,103,181–72,104,209, 1 gene (within-gene range 0–2): ABCF2P2.
- chr7:142,626,649–142,802,748, 36 genes: TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2.
- chr10:70,672,506–70,762,441, 1 gene: ADAMTS14.
- chr12:129,839,928–129,854,944, 2 genes (within-gene range 0–2): AC055717.3, AC055717.1.
- chr14:21,950,406–22,552,156, 109 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 65. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
